Somatic mutation profile of cancer-model specimen HCM-STAN-0909-C16-85A (3D Organoid, passage 6; aliquot HCM-STAN-0909-C16-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-STAN-0909-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen HCM-STAN-0909-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6194504e-cb4e-4a03-b58a-f0cd6c898e0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0909-C16-11A (FFPE Scrolls), aliquot HCM-STAN-0909-C16-11A-03D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d68e5eb5-7307-41df-87d3-32ebe3764207

The open-access MAF lists 1,654 somatic variants for this specimen: 1,163 protein-altering or splice-affecting, 435 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 848, Silent 435, Frame Shift Del 195, Frame Shift Ins 57, Nonsense Mutation 48, Intron 27, 5'UTR 10, Splice Region 7, 3'UTR 7, 5'Flank 6, RNA 4, In Frame Del 3.

Variants (750 of 1,654; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOE | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 50/740 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906567, CM043808, CM890009; ClinVar: pathogenic; called by muse, mutect2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 310/642 reads (48%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FAH | c.615dup p.V206Cfs*18 | Frame Shift Ins (INS) | VAF 129/272 reads (47%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 135/392 reads (34%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.9265dup p.V3089Gfs*9 | Frame Shift Ins (INS) | VAF 111/533 reads (21%) | catalogued as rs1333678798; ClinVar: pathogenic; called by mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 100/222 reads (45%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MAK | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 165/333 reads (50%) | catalogued as rs753314164, COSV57564849; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 254/518 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs377491278, CM1410892; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 208/431 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTLL5 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 132/270 reads (49%) | catalogued as rs766173950; ClinVar: likely pathogenic; called by muse, varscan2
- WRN | c.3382dup p.S1128Kfs*37 | Frame Shift Ins (INS) | VAF 66/224 reads (29%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, varscan2
- A2M | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769180200; called by muse, mutect2, varscan2
- AATK | c.2395G>A p.V799I (on ENST00000326724 / NM_001080395.3; = p.V696I on NM_004920.2) | Missense Mutation (SNP) | VAF 326/632 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs200566125; called by muse, mutect2, varscan2
- ABCB4 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 301/574 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55935600; called by muse, mutect2, varscan2
- ABCC10 | c.2350C>T p.R784C (on ENST00000372530 / NM_001198934.2; = p.R756C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 309/619 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs374074845; called by muse, mutect2, varscan2
- ABCC6 | c.1431+1G>A p.X477_splice | Splice Site (SNP) | VAF 161/339 reads (47%) | catalogued as COSV52745347; called by muse, mutect2, varscan2
- ABCF3 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 271/775 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766065416; called by muse, mutect2, varscan2
- ABHD8 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 196/398 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs552233794; called by muse, mutect2, varscan2
- AC099489.1 | c.8615G>A p.R2872Q | Missense Mutation (SNP) | VAF 20/622 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1234072402; called by muse, mutect2
- AC105001.2 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 121/250 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs773492827; called by muse, mutect2, varscan2
- ACAA1 | c.1105del p.L369Wfs*7 | Frame Shift Del (DEL) | VAF 235/503 reads (47%) | catalogued as COSV100086020; called by mutect2, varscan2
- ACOX2 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 200/419 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs778657401; called by muse, mutect2, varscan2
- ACSS2 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1202398973; called by muse, mutect2, varscan2
- ACTG2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 172/359 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs765884368, COSV61827627; called by muse, mutect2, varscan2
- ADAD1 | c.1581del p.E528Nfs*25 | Frame Shift Del (DEL) | VAF 121/250 reads (48%) | catalogued as COSV99635918; called by mutect2, varscan2
- ADAM20 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 241/535 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs138842334; called by muse, mutect2, varscan2
- ADAM21 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 115/247 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs144574931; called by muse, mutect2, varscan2
- ADAMTS14 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 273/543 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776328715, COSV64600156; called by muse, mutect2, varscan2
- ADAMTS7 | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1201056103; called by mutect2, varscan2
- ADAMTS9 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 222/430 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs777923818, COSV55784952; called by muse, mutect2, varscan2
- ADCY7 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 190/366 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs141712991; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 171/378 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by muse, mutect2, varscan2
- ADGRB3 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 174/346 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773707304, COSV101000410, COSV65401204; called by muse, varscan2
- ADGRE2 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 253/530 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs144104308; called by muse, mutect2, varscan2
- ADGRL1 | c.3370G>A p.G1124R (on ENST00000340736 / NM_001008701.3; = p.G1119R on NM_014921.5) | Missense Mutation (SNP) | VAF 197/394 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as rs200651279; called by muse, mutect2, varscan2
- ADORA3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 243/518 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.716); catalogued as rs145233928; called by muse, mutect2, varscan2
- AGPAT4 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 268/563 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as rs772732213; called by muse, mutect2, varscan2
- AIPL1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 307/602 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as rs148543951; called by muse, mutect2, varscan2
- AKAP3 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 191/392 reads (49%) | catalogued as rs375207041; called by muse, varscan2
- AKT3 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 237/470 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55629231; called by muse, mutect2, varscan2
- ALG1L2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 216/446 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs779974595; called by muse, mutect2, varscan2
- ALG1L2 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs370245000; called by muse, varscan2
- AMHR2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 196/389 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1452594237; called by muse, mutect2, varscan2
- AMZ2 | c.97del p.E33Nfs*4 | Frame Shift Del (DEL) | VAF 211/405 reads (52%) | catalogued as rs1555738505; called by mutect2, varscan2
- ANK2 | c.11474T>C p.I3825T | Missense Mutation (SNP) | VAF 251/523 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as rs1460900882; called by muse, varscan2
- ANKRD33B | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 259/544 reads (48%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.506); catalogued as rs1047812642; called by muse, varscan2
- ANKRD33B | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 280/552 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.419); catalogued as rs1423086709; called by muse, varscan2
- ANKRD35 | c.2519G>A p.G840D | Missense Mutation (SNP) | VAF 292/580 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs781847273; called by muse, mutect2, varscan2
- ANKRD36 | c.3437C>T p.T1146M | Missense Mutation (SNP) | VAF 162/503 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs375718563; called by muse, mutect2, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 106/235 reads (45%) | catalogued as rs774510795; called by mutect2, varscan2
- ANO2 | c.2524G>A p.G842S (on ENST00000356134 / NM_001278597.3; = p.G846S on NM_001278596.3) | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549254794, COSV59032212; called by muse, mutect2, varscan2
- AOAH | c.1643A>G p.Q548R | Missense Mutation (SNP) | VAF 221/463 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs776443004; called by muse, mutect2, varscan2
- AP3S1 | c.576T>A p.F192L | Missense Mutation (SNP) | VAF 75/401 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs746798470; called by muse, mutect2
- AP5S1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 253/528 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs776927558; called by muse, mutect2, varscan2
- AP5Z1 | c.2086dup p.Q696Pfs*67 | Frame Shift Ins (INS) | VAF 256/506 reads (51%) | catalogued as rs771683676; called by mutect2, varscan2
- APBB1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 198/443 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773975178; called by muse, mutect2, varscan2
- APOE | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 307/673 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs778237451; called by muse, mutect2, varscan2
- APP | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 160/344 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.496); catalogued as rs755525590; called by muse, mutect2, varscan2
- ARAP1 | c.2783G>A p.R928Q (on ENST00000393609 / NM_001040118.2; = p.R683Q on NM_015242.4) | Missense Mutation (SNP) | VAF 235/488 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs532431878; called by muse, mutect2, varscan2
- ARG1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 178/387 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs182650447; called by muse, varscan2
- ARHGAP44 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 266/526 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs1218260293; called by muse, mutect2, varscan2
- ARHGEF18 | c.2854C>T p.R952C (on ENST00000359920 / NM_001130955.2; = p.R848C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 398/865 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749113504, COSV60471680; ClinVar: uncertain significance; called by muse, mutect2
- ARPP21 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 208/428 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1246062557, COSV51793728; called by muse, mutect2, varscan2
- ARRDC1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 324/598 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs371706149; called by muse, varscan2
- ARSG | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 160/341 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs150072981, COSV71593277; called by muse, varscan2
- ASCC2 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 174/344 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs750937631; called by muse, mutect2, varscan2
- ASTN1 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746027441, COSV62496884; called by muse, mutect2, varscan2
- ASTN2 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 292/585 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1483625703, COSV100531368; called by muse, varscan2
- ATP10A | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 270/529 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as COSV63518915; called by muse, mutect2, varscan2
- ATP5F1A | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 129/308 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); catalogued as rs201477144, COSV56362020; called by muse, mutect2, varscan2
- ATXN1 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 286/607 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55224294; called by muse, mutect2, varscan2
- ATXN7L3 | c.605G>A p.R202H (on ENST00000389384 / NM_001382309.1; = p.R209H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/283 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs751741019, COSV60228645; called by muse, mutect2, varscan2
- AXIN1 | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 255/505 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs756690670, COSV51985788; called by muse, mutect2, varscan2
- AXIN2 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 314/590 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs773033390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 151/168 reads (90%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAHCC1 | c.4812del p.R1605Afs*107 | Frame Shift Del (DEL) | VAF 262/576 reads (45%) | catalogued as rs1555657301, COSV57027984; called by mutect2, varscan2
- BAIAP3 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 194/380 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201353225, COSV99136218; called by muse, varscan2
- BCL11A | c.1914del p.F639Sfs*117 (on ENST00000335712 / NM_001365609.1; = p.F673Sfs*105 on NM_018014.4) | Frame Shift Del (DEL) | VAF 276/527 reads (52%) | catalogued as COSV100186676; called by mutect2, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 259/532 reads (49%) | catalogued as rs758526156; called by mutect2, varscan2
- BECN2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 308/620 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61560426; called by muse, mutect2, varscan2
- BHLHA9 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 303/640 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1354091588; called by muse, mutect2, varscan2
- BHLHE22 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 304/984 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58862253; called by muse, varscan2
- BHLHE23 | c.128C>T p.P43L (on ENST00000370346; = p.P59L on NM_080606.4) | Missense Mutation (SNP) | VAF 279/492 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1304128792; called by muse, mutect2, varscan2
- BIRC6 | c.8575G>A p.V2859M | Missense Mutation (SNP) | VAF 187/382 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs570853275; called by muse, mutect2, varscan2
- BIRC6 | c.11801G>A p.R3934H | Missense Mutation (SNP) | VAF 200/418 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766431375, COSV70198526; called by muse, mutect2, varscan2
- BRINP2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 212/423 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs745381993; called by muse, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 102/222 reads (46%) | catalogued as rs1455506786, COSV59000653; called by mutect2, varscan2
- C1QB | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs200457185, COSV59245414; called by muse, mutect2, varscan2
- C1orf210 | c.121del p.A41Lfs*87 | Frame Shift Del (DEL) | VAF 280/556 reads (50%) | catalogued as rs1557429838; called by mutect2, varscan2
- C3 | c.2323G>A p.V775I | Missense Mutation (SNP) | VAF 189/390 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs745813592; called by muse, mutect2, varscan2
- C5orf49 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 186/405 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs761410234, COSV57883149; called by muse, mutect2, varscan2
- C6orf132 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 218/466 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs985827803; called by muse, mutect2, varscan2
- C6orf132 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 154/262 reads (59%) | SIFT deleterious, low confidence (0.01); catalogued as rs1388209267; called by mutect2, varscan2
- CACNA1E | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 344/699 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs986188761, COSV62406496, COSV62407370; called by muse, mutect2, varscan2
- CACNG8 | c.1084del p.A362Rfs*98 | Frame Shift Del (DEL) | VAF 74/155 reads (48%) | catalogued as rs1196747223; called by mutect2, varscan2
- CAPN11 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 174/409 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs759229375, COSV67236425; called by muse, mutect2, varscan2
- CAPN9 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 218/480 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773793654; called by muse, mutect2, varscan2
- CARD10 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 197/401 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs759948361; called by muse, mutect2, varscan2
- CASKIN1 | c.4012G>A p.V1338M | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as rs1263140687; called by muse, mutect2, varscan2
- CASP9 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 181/358 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61602650; called by muse, mutect2, varscan2
- CBFA2T3 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 314/640 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.041); catalogued as rs375495507; called by muse, mutect2, varscan2
- CCAR2 | c.1513dup p.L505Pfs*32 | Frame Shift Ins (INS) | VAF 199/670 reads (30%) | catalogued as rs748274275; called by mutect2, varscan2
- CCDC102A | c.496dup p.V166Gfs*20 | Frame Shift Ins (INS) | VAF 204/402 reads (51%) | catalogued as rs1179119748; called by mutect2, varscan2
- CCDC171 | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as rs372373322; called by muse, mutect2, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 119/275 reads (43%) | catalogued as rs747131147; called by mutect2, varscan2
- CDC16 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 201/385 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as rs777641032, COSV52961401, COSV52962724; called by muse, mutect2, varscan2
- CDH17 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 113/392 reads (29%) | catalogued as rs778286335, COSV99217814; called by muse, varscan2
- CDH3 | c.2117del p.G706Vfs*53 | Frame Shift Del (DEL) | VAF 135/295 reads (46%) | catalogued as rs774982244; called by mutect2, varscan2
- CDH4 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 248/598 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556825432, COSV64650628; called by muse, mutect2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 292/575 reads (51%) | catalogued as rs749463697; called by mutect2, varscan2
- CDK5R2 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 262/558 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1035266904, COSV56937621; called by muse, mutect2, varscan2
- CDK9 | c.627del p.I210Lfs*66 | Frame Shift Del (DEL) | VAF 206/423 reads (49%) | catalogued as rs755440676; called by mutect2, varscan2
- CDYL | c.1663G>A p.V555M (on ENST00000328908 / NM_001368125.1; = p.V501M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/338 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); catalogued as rs146123232; called by muse, mutect2, varscan2
- CELA1 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV53329079; called by muse, mutect2, varscan2
- CELSR3 | c.4550C>T p.A1517V | Missense Mutation (SNP) | VAF 334/695 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1016865776; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 94/172 reads (55%) | catalogued as rs1325731082; called by mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 116/248 reads (47%) | catalogued as COSV100071584; called by mutect2, varscan2
- CEP170 | c.4184C>T p.P1395L | Missense Mutation (SNP) | VAF 192/471 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs201404435; called by muse, mutect2, varscan2
- CERS6 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 172/327 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs781249433; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 158/360 reads (44%) | catalogued as rs747835123, COSV61504174; called by mutect2, varscan2
- CFAP43 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs760441978, COSV53382016; called by muse, mutect2, varscan2
- CGN | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148637517; called by muse, varscan2
- CGN | c.2519T>C p.L840P | Missense Mutation (SNP) | VAF 261/556 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483824874; called by muse, mutect2, varscan2
- CHD5 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 216/482 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs778454890; called by muse, mutect2, varscan2
- CHST12 | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 298/605 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1191965837; called by muse, mutect2, varscan2
- CHST13 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 294/574 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.145); catalogued as rs1244200401; called by muse, mutect2, varscan2
- CKAP5 | c.3932C>T p.A1311V | Missense Mutation (SNP) | VAF 176/349 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs766170007, COSV56368132; called by muse, mutect2, varscan2
- CLCN2 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 212/597 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV99658458; called by muse, mutect2, varscan2
- CLIC1 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 72/862 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101007436; called by muse, mutect2
- CLN3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765893479; called by muse, mutect2, varscan2
- CLTB | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 190/386 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777822872, COSV60043875; called by muse, mutect2, varscan2
- CMTM5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 269/498 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.682); catalogued as rs756622705, COSV100198194; called by muse, mutect2, varscan2
- CNOT3 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 317/670 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55359762; called by muse, mutect2, varscan2
- CNTLN | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 130/247 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751605497, COSV52065343; called by muse, mutect2, varscan2
- CNTN6 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 188/404 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199663087; called by muse, mutect2, varscan2
- COL11A1 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 144/341 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62190932; called by muse, mutect2, varscan2
- COL18A1 | c.3160G>A p.G1054R (on ENST00000359759 / NM_130444.3; = p.G819R on NM_030582.4) | Missense Mutation (SNP) | VAF 212/480 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV60589150; called by muse, mutect2, varscan2
- COL18A1 | c.4594C>T p.R1532W (on ENST00000359759 / NM_130444.3; = p.R1297W on NM_030582.4) | Missense Mutation (SNP) | VAF 250/494 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs556925757; called by muse, mutect2, varscan2
- COL25A1 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 157/364 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1377615578, COSV67654947; called by muse, mutect2, varscan2
- COL27A1 | c.1908G>T p.P636= | Splice Region (SNP) | VAF 158/343 reads (46%) | catalogued as COSV100620750; called by muse, mutect2
- COL27A1 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs748351189, COSV100621524; called by muse, mutect2, varscan2
- COPZ1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 157/331 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs779205641; called by muse, mutect2, varscan2
- CORO7 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 308/647 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs766836793, COSV52031780, COSV99227487; called by muse, mutect2, varscan2
- CPD | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 173/374 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs61745982; called by muse, mutect2, varscan2
- CPN2 | c.701del p.P234Lfs*10 | Frame Shift Del (DEL) | VAF 220/750 reads (29%) | catalogued as COSV100103034; called by mutect2, varscan2
- CRACD | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 333/632 reads (53%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1282697985, COSV99949037; called by muse, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 248/480 reads (52%) | catalogued as COSV51715473; called by mutect2, varscan2
- CRAMP1 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 250/560 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1261501449, COSV51961862; called by muse, mutect2, varscan2
- CRB2 | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 315/666 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as COSV63502093; called by muse, mutect2, varscan2
- CRIM1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 215/450 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1045365045; called by muse, mutect2, varscan2
- CRYGD | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV52206159, COSV52206277; called by muse, mutect2, varscan2
- CSF1R | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 362/726 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.397); catalogued as rs765232439, COSV53836653, COSV53844104; called by muse, mutect2, varscan2
- CSMD3 | c.4964T>C p.I1655T (on ENST00000297405 / NM_001363185.1; = p.I1551T on NM_052900.3) | Missense Mutation (SNP) | VAF 183/606 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1188247091; called by muse, varscan2
- CSN3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 233/489 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs143899003; called by muse, mutect2, varscan2
- CSNK1A1L | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 246/486 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.419); catalogued as rs373362769; called by muse, mutect2, varscan2
- CTBP2 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 205/425 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs1455608344; called by muse, mutect2, varscan2
- CTHRC1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 197/554 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as rs147175675, COSV57715602; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 216/498 reads (43%) | catalogued as rs758642867; called by mutect2, varscan2
- CTSC | c.1154del p.K385Rfs*9 | Frame Shift Del (DEL) | VAF 210/468 reads (45%) | catalogued as rs34638651; called by mutect2, varscan2
- CUL9 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758017460, COSV99335352; called by muse, mutect2, varscan2
- CXXC5 | c.168dup p.E57Rfs*11 | Frame Shift Ins (INS) | VAF 230/462 reads (50%) | catalogued as rs756380231; called by mutect2, varscan2
- CYLC2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 275/541 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs199562230; called by muse, mutect2, varscan2
- DAAM2 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 216/436 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs751737330, COSV51303681; called by muse, varscan2
- DAZAP1 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 246/511 reads (48%) | catalogued as COSV51830928; called by muse, mutect2, varscan2
- DBH | c.157del p.L53Wfs*91 | Frame Shift Del (DEL) | VAF 294/584 reads (50%) | catalogued as COSV55040104; called by mutect2, varscan2
- DBR1 | c.521A>G p.H174R | Missense Mutation (SNP) | VAF 195/295 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs745912274; called by muse, mutect2, varscan2
- DBX2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs146059128; called by muse, mutect2, varscan2
- DCTN1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 198/388 reads (51%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.885); catalogued as rs753892865; called by muse, mutect2, varscan2
- DENND4B | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 190/396 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs373068402, COSV63408673; called by muse, varscan2
- DEPDC5 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 140/299 reads (47%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.795); catalogued as COSV56694358, COSV56701951; called by muse, mutect2, varscan2
- DGKQ | c.2554G>A p.V852M | Missense Mutation (SNP) | VAF 198/394 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280768523; called by muse, mutect2, varscan2
- DGKQ | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 333/699 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs936982279; called by muse, mutect2, varscan2
- DHCR7 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 77/421 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.218); catalogued as rs532635888, COSV104416537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX29 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs61730834; called by muse, mutect2, varscan2
- DIDO1 | c.6211C>T p.R2071* | Nonsense Mutation (SNP) | VAF 314/598 reads (53%) | catalogued as COSV56617994; called by muse, varscan2
- DIDO1 | c.4694G>A p.R1565H | Missense Mutation (SNP) | VAF 292/630 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99827680; called by muse, mutect2, varscan2
- DNAH12 | c.5374C>T p.R1792C (on ENST00000351747; = p.R1811C on NM_001366028.2) | Missense Mutation (SNP) | VAF 200/388 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195038562, COSV61054314; called by muse, mutect2, varscan2
- DNAH17 | c.1729del p.L577* | Frame Shift Del (DEL) | VAF 154/344 reads (45%) | catalogued as rs1568258951; called by mutect2, varscan2
- DNAH5 | c.13849G>A p.V4617I | Missense Mutation (SNP) | VAF 185/425 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs923678039, COSV54236793; called by muse, mutect2, varscan2
- DNAH6 | c.9875G>A p.R3292H | Missense Mutation (SNP) | VAF 291/570 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs776576636, COSV52885954, COSV52888538; called by muse, mutect2, varscan2
- DNAJC13 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 179/356 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs752144375; called by muse, mutect2, varscan2
- DNHD1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 260/510 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs781073836, COSV54437199; called by muse, mutect2, varscan2
- DNHD1 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 221/468 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1220943420, COSV99601185; called by muse, varscan2
- DNMBP | c.2933G>A p.R978H | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377176374; called by muse, mutect2, varscan2
- DNTT | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 136/337 reads (40%) | catalogued as rs369785092; called by muse, mutect2, varscan2
- DOCK10 | c.1122dup p.D375Rfs*6 | Frame Shift Ins (INS) | VAF 118/272 reads (43%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK6 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 262/552 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs369679393; called by muse, mutect2, varscan2
- DPP8 | c.479G>A p.R160H (on ENST00000341861 / NM_001320875.2; = p.R144H on NM_017743.6) | Missense Mutation (SNP) | VAF 193/393 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373358439, COSV55682381; called by muse, mutect2, varscan2
- DPYD | c.1764del p.R589Efs*20 | Frame Shift Del (DEL) | VAF 96/210 reads (46%) | catalogued as rs1346124437; ClinVar: uncertain significance; called by mutect2, varscan2
- DPYSL3 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 146/330 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV100574972; called by muse, mutect2, varscan2
- DRD2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 292/605 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748462272, COSV60754096; called by muse, mutect2, varscan2
- DUS1L | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 212/474 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.362); catalogued as rs972975745; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 119/225 reads (53%) | catalogued as rs746928635; called by mutect2, varscan2
- EBF3 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 162/334 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1424149391; called by muse, varscan2
- EEF1AKMT4-ECE2 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 130/509 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs545716291, COSV62570319; called by muse, mutect2, varscan2
- EEF1AKNMT | c.2057C>T p.T686M (on ENST00000361735 / NM_015935.5; = p.T600M on NM_014955.3) | Missense Mutation (SNP) | VAF 181/386 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as rs201514759; called by muse, mutect2, varscan2
- EEF2 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 225/457 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.438); catalogued as rs1288346216, COSV58578665; called by muse, mutect2, varscan2
- EFCAB12 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 222/502 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs542010344, COSV58174782; called by muse, mutect2, varscan2
- EFCAB8 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 170/378 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV68700188; called by muse, mutect2, varscan2
- EFHB | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 244/513 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs374916444; called by muse, mutect2, varscan2
- EID2B | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 283/617 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs1256107250; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 144/262 reads (55%) | catalogued as rs748937918; called by mutect2, varscan2
- ELAVL4 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 175/389 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs138779266; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 264/582 reads (45%) | catalogued as rs769175197; called by mutect2, varscan2
- EMID1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 250/487 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs200384180; called by muse, mutect2, varscan2
- EML6 | c.5024dup p.N1675Kfs*5 | Frame Shift Ins (INS) | VAF 158/344 reads (46%) | catalogued as rs1008972663; called by mutect2, varscan2
- ENC1 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 216/487 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs1209077143, COSV56629552; called by muse, mutect2, varscan2
- EP300 | c.1353del p.N452Tfs*2 | Frame Shift Del (DEL) | VAF 138/305 reads (45%) | catalogued as COSV54328933; called by mutect2, varscan2
- EP400 | c.8453C>A p.P2818Q | Missense Mutation (SNP) | VAF 360/755 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV57778566; called by muse, mutect2, varscan2
- EPM2AIP1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 262/585 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV51614974; called by muse, mutect2, varscan2
- ERBB2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 243/470 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs113619125, COSV54069078; called by muse, mutect2, varscan2
- ERBB4 | c.3467A>G p.D1156G | Missense Mutation (SNP) | VAF 159/343 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.141); catalogued as rs373818748; called by muse, mutect2, varscan2
- ERICH6B | c.950del p.K317Rfs*18 | Frame Shift Del (DEL) | VAF 114/256 reads (45%) | catalogued as rs754232917, COSV100074795; called by mutect2, varscan2
- EVX2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 283/618 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57962699; called by muse, mutect2, varscan2
- EXPH5 | c.314del p.N105Mfs*2 | Frame Shift Del (DEL) | VAF 126/274 reads (46%) | catalogued as rs772652329; called by mutect2, varscan2
- EYS | c.2854dup p.C952Lfs*2 | Frame Shift Ins (INS) | VAF 76/204 reads (37%) | catalogued as rs779877426; called by mutect2, varscan2
- FAM110A | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 311/654 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs767515662; called by muse, mutect2, varscan2
- FAM110D | c.725del p.P242Rfs*113 | Frame Shift Del (DEL) | VAF 278/521 reads (53%) | catalogued as rs1346186047; called by mutect2, varscan2
- FAM120C | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1385861209; called by muse, mutect2, varscan2
- FAM135B | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 220/681 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs554108334, COSV52704532; called by muse, mutect2, varscan2
- FAM71A | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 268/516 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs762536409; called by muse, mutect2, varscan2
- FAM78A | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 295/563 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs545925341, COSV64844329; called by muse, mutect2, varscan2
- FANCM | c.2366A>G p.D789G | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs779657352; called by muse, mutect2, varscan2
- FARP1 | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 226/493 reads (46%) | catalogued as rs549979587, COSV60330327; called by muse, mutect2
- FASN | c.6449C>T p.A2150V | Missense Mutation (SNP) | VAF 278/559 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1461481001, COSV60759412; called by muse, mutect2, varscan2
- FAT4 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 216/436 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV67895874; called by muse, varscan2
- FBLL1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 225/472 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1561832960; called by muse, mutect2, varscan2
- FBXL2 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 148/317 reads (47%) | catalogued as rs762197933, COSV99372100; called by muse, mutect2, varscan2
- FBXO9 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372104960; called by muse, varscan2
- FBXW5 | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 411/783 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs111646697; called by muse, mutect2, varscan2
- FERMT3 | c.1925C>T p.S642L (on ENST00000279227 / NM_178443.3; = p.S638L on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 244/515 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1305088399, COSV54174231; called by muse, mutect2, varscan2
- FGF22 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 302/644 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1053327160, COSV51260890; called by mutect2, varscan2
- FHDC1 | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 199/432 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1561214564; called by muse, mutect2, varscan2
- FLT4 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760862462, COSV56117306; called by muse, varscan2
- FOXC2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 191/364 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as CD021827; called by muse, mutect2, varscan2
- FOXE3 | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 110/186 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as rs954703925, COSV58632947; called by muse, varscan2
- FOXK1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 289/602 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1003844502, COSV61068538; called by muse, varscan2
- FOXK1 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 310/596 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as rs778526385, COSV100194444; called by muse, varscan2
- FOXO3 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 199/428 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370043657, COSV59627459; called by muse, mutect2, varscan2
- FRAT2 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 18/606 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1334632874; called by muse, mutect2
- FRK | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 237/487 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- FRMD8 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 217/434 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs772838434; called by muse, mutect2, varscan2
- FZD8 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 290/612 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV65967793; called by muse, mutect2, varscan2
- GABRR1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 203/434 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs748601302, COSV101033915, COSV65620053; called by muse, mutect2
- GBP7 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 181/397 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs142086618; called by muse, varscan2
- GCKR | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 149/297 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs563921371, COSV53107046; called by muse, varscan2
- GDF11 | c.136del p.E46Sfs*31 | Frame Shift Del (DEL) | VAF 107/211 reads (51%) | catalogued as rs1412840296; called by mutect2, varscan2
- GDF3 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 221/413 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145849916, COSV61712909; called by muse, mutect2, varscan2
- GFM1 | c.2015A>G p.H672R | Missense Mutation (SNP) | VAF 178/587 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1216221823; called by muse, varscan2
- GIMAP1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 360/711 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs774189459; called by muse, mutect2, varscan2
- GJD4 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 209/469 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781750287, COSV58703078; called by muse, mutect2, varscan2
- GLRB | c.335A>T p.N112I | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs1228266830; called by muse, mutect2
- GOLGA2 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 216/507 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV101425853; called by muse, mutect2, varscan2
- GOLGA6B | c.1855G>T p.G619W | Missense Mutation (SNP) | VAF 98/1098 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs1392537256; called by muse, mutect2
- GPR135 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 246/502 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1183831032; called by muse, mutect2, varscan2
- GPR27 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 238/521 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as rs1301236038, COSV55207281; called by muse, mutect2, varscan2
- GPR75 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 258/511 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746727233; called by muse, mutect2, varscan2
- GPT | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 247/828 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs777851951; called by muse, mutect2, varscan2
- GPX5 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 245/480 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs371361550; called by muse, varscan2
- GRIN2C | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 220/420 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV53118409; called by muse, varscan2
- GRM6 | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 294/567 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs867185590; called by muse, mutect2, varscan2
- GSDMD | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 274/889 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs751529628; called by muse, mutect2, varscan2
- GTF3C1 | c.2356G>A p.G786R | Missense Mutation (SNP) | VAF 120/280 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749101392; called by muse, mutect2, varscan2
- GUCY1B1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 174/396 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs528249414, COSV52375949; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 130/321 reads (40%) | catalogued as COSV54945907; called by mutect2, varscan2
- H1-6 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs1272603620, COSV58089962; called by muse, mutect2, varscan2
- H1-7 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 302/583 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as COSV58602128; called by muse, mutect2, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 204/438 reads (47%) | catalogued as CM105646; called by mutect2, varscan2
- HAND2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 294/595 reads (49%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV64018256; called by mutect2, varscan2
- HDAC6 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782443971, COSV61927772; called by muse, varscan2
- HECW1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 278/603 reads (46%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs751728485, COSV67826141; called by muse, mutect2, varscan2
- HECW1 | c.3083C>T p.T1028M | Missense Mutation (SNP) | VAF 160/306 reads (52%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.61); catalogued as rs374098288; called by muse, mutect2, varscan2
- HECW2 | c.610A>G p.N204D | Missense Mutation (SNP) | VAF 158/349 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53651200; called by muse, mutect2, varscan2
- HELZ2 | c.3140C>A p.A1047E (on ENST00000467148 / NM_001037335.2; = p.A478E on NM_033405.3) | Missense Mutation (SNP) | VAF 242/506 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64409302; called by muse, mutect2, varscan2
- HERC2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 308/614 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770718313, COSV55337307; called by muse, mutect2, varscan2
- HERC6 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 147/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369219414; called by muse, mutect2, varscan2
- HOXD11 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.385); catalogued as rs544796078, COSV50910521; called by muse, mutect2, varscan2
- HPSE | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 182/444 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV60986801; called by muse, mutect2, varscan2
- HSD11B2 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 212/443 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1139495, COSV99340979; called by muse, mutect2, varscan2
- HSD17B14 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 199/418 reads (48%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs760796044, COSV54414915; called by muse, mutect2, varscan2
- HSD17B14 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 273/579 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs565045362, COSV54365019; called by muse, mutect2, varscan2
- HSPG2 | c.12394C>T p.R4132* | Nonsense Mutation (SNP) | VAF 172/348 reads (49%) | catalogued as rs745544664; called by muse, mutect2, varscan2
- HSPG2 | c.4280G>A p.G1427D | Missense Mutation (SNP) | VAF 239/477 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269102422; called by muse, mutect2, varscan2
- HTR1E | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 250/581 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.416); catalogued as rs764472292, COSV100541091, COSV59511258; called by muse, mutect2, varscan2
- HTR2A | c.1289del p.K430Rfs*19 | Frame Shift Del (DEL) | VAF 199/383 reads (52%) | catalogued as rs1398128295; called by mutect2, varscan2
- HTR3D | c.380C>T p.S127F (on ENST00000382489 / NM_001163646.2; = p.S66F on NM_001145143.1) | Missense Mutation (SNP) | VAF 156/428 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1451495526; called by muse, mutect2, varscan2
- HTR6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 356/763 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57034832; called by muse, mutect2
- ICAM1 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441940436; called by muse, mutect2, varscan2
- IDNK | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 206/411 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as rs777890451; called by muse, mutect2, varscan2
- IGSF9 | c.2464del p.D822Ifs*33 (on ENST00000368094 / NM_001135050.2; = p.D806Ifs*33 on NM_020789.4) | Frame Shift Del (DEL) | VAF 240/542 reads (44%) | catalogued as COSV57423607; called by mutect2, varscan2
- IL17F | c.122dup p.Q42Pfs*4 | Frame Shift Ins (INS) | VAF 168/369 reads (46%) | catalogued as rs771763707; called by mutect2, varscan2
- IL17RB | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 222/422 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs778086828, COSV99213679; called by muse, mutect2, varscan2
- INO80D | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 184/338 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs557304541, COSV101305790; called by muse, mutect2, varscan2
- INTS11 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 248/472 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997507615; called by muse, mutect2, varscan2
- IPO13 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV64893745; called by muse, mutect2, varscan2
- IQCM | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 221/412 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1487978600; called by muse, mutect2, varscan2
- IQGAP2 | c.3832A>G p.I1278V | Missense Mutation (SNP) | VAF 254/491 reads (52%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as rs776113927; called by muse, mutect2, varscan2
- IRF3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 304/610 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768649559; called by muse, mutect2, varscan2
- IRS2 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 187/370 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as rs1284382975; called by muse, mutect2, varscan2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 210/462 reads (45%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by mutect2, varscan2
- JADE1 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 123/252 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as COSV56905333; called by muse, varscan2
- JAKMIP1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 357/693 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51528285; called by muse, mutect2, varscan2
- JMY | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 109/557 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as rs554608602; called by muse, mutect2, varscan2
- JPH1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 306/906 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1294087636, COSV100646338; called by muse, varscan2
- KANSL1 | c.2018A>G p.D673G | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV52270427; called by muse, mutect2, varscan2
- KAT6A | c.1285del p.E429Kfs*49 | Frame Shift Del (DEL) | VAF 240/746 reads (32%) | catalogued as rs1564034388; called by mutect2, varscan2
- KAT6B | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 282/610 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54742244; called by muse, mutect2, varscan2
- KATNIP | c.3602C>T p.T1201M | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs754317109; called by muse, mutect2, varscan2
- KCNA5 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 257/553 reads (46%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs201328038; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KCNB1 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 222/474 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs755481445, COSV100870504; called by muse, mutect2, varscan2
- KCND2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 246/515 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs1410148488; called by muse, mutect2, varscan2
- KCND2 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 191/397 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs757409386, COSV58592426; called by muse, varscan2
- KCNH3 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 164/344 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378968477, COSV57792676, COSV99235449; called by muse, mutect2, varscan2
- KCNH3 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 304/569 reads (53%) | catalogued as COSV57789938; called by muse, mutect2, varscan2
- KCNH8 | c.1211C>G p.S404C | Missense Mutation (SNP) | VAF 141/262 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100111162, COSV60455785; called by muse, varscan2
- KCNH8 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1160540365, COSV60479598; called by muse, varscan2
- KCNJ5 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as rs771161358, COSV57965318; called by muse, mutect2, varscan2
- KHSRP | c.653dup p.G221Rfs*37 | Frame Shift Ins (INS) | VAF 176/434 reads (41%) | catalogued as COSV101231117; called by mutect2, varscan2
- KIAA0100 | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 176/341 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762692859, COSV66490901; called by muse, mutect2, varscan2
- KIAA0319L | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs750623856, COSV57845436; called by muse, mutect2, varscan2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 244/491 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, varscan2
- KIF15 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 194/390 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs766745002; called by muse, mutect2, varscan2
- KIF24 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 266/562 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs544772730, COSV52662316; called by muse, mutect2, varscan2
- KIF26B | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 390/824 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373427955; called by muse, mutect2, varscan2
- KIFC2 | c.2368del p.L790Yfs*84 | Frame Shift Del (DEL) | VAF 281/832 reads (34%) | catalogued as COSV56760889; called by mutect2, varscan2
- KL | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 208/469 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs775908357; called by muse, mutect2, varscan2
- KLF10 | c.911del p.P304Lfs*31 | Frame Shift Del (DEL) | VAF 224/665 reads (34%) | catalogued as rs771864173; called by mutect2, varscan2
- KLF3 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 166/361 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV54710989; called by muse, mutect2, varscan2
- KLHL26 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 339/694 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV56316120; called by muse, mutect2, varscan2
- KLHL29 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 338/672 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1351348306; called by muse, mutect2, varscan2
- KLHL30 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 313/658 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs369875701; called by muse, mutect2, varscan2
- KLK2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 161/369 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs374929405; called by muse, mutect2, varscan2
- KNDC1 | c.4066del p.L1356Wfs*109 | Frame Shift Del (DEL) | VAF 198/388 reads (51%) | catalogued as rs1357824752; called by mutect2, varscan2
- L1CAM | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 264/265 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781908326, COSV62827252; ClinVar: benign / uncertain significance; called by muse, varscan2
- L3MBTL4 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 163/375 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755021468, COSV53145999; called by muse, mutect2, varscan2
- LAMA5 | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 354/746 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs778474043; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 158/346 reads (46%) | catalogued as rs1311334991; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 126/284 reads (44%) | catalogued as COSV60222740; called by mutect2, varscan2
- LCAT | c.101dup p.H35Afs*7 | Frame Shift Ins (INS) | VAF 256/510 reads (50%) | catalogued as rs967875404; called by mutect2, varscan2
- LGALS9C | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs371253004; called by muse, mutect2, varscan2
- LGI4 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 273/623 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs775448533; called by muse, mutect2, varscan2
- LHB | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 311/564 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201749590, COSV55484053; called by muse, mutect2, varscan2
- LHFPL5 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 212/467 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755791421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINGO4 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 292/590 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs772746600; called by muse, mutect2, varscan2
- LMF1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 327/659 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs778529081, COSV51902501; called by muse, mutect2, varscan2
- LMNB2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 188/402 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs772843683, COSV57589634; called by muse, varscan2
- LMOD3 | c.637dup p.I213Nfs*7 | Frame Shift Ins (INS) | VAF 206/420 reads (49%) | catalogued as rs773282804; called by mutect2, varscan2
- LOXHD1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1164980356; called by muse, mutect2, varscan2
- LPAR2 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 53/613 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759629694, COSV52555319; called by muse, mutect2
- LPIN1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 252/518 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774490262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1 | c.4829C>T p.T1610M | Missense Mutation (SNP) | VAF 213/444 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1240179235, COSV54528309; called by muse, mutect2, varscan2
- LRP1 | c.5387-1G>A p.X1796_splice | Splice Site (SNP) | VAF 184/365 reads (50%) | catalogued as COSV54520516; called by muse, mutect2, varscan2
- LRP1B | c.10337C>T p.T3446M | Missense Mutation (SNP) | VAF 159/381 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs748759183, COSV67182342; called by muse, mutect2, varscan2
- LRRC46 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 98/224 reads (44%) | catalogued as rs748743875, COSV51635956; called by muse, mutect2, varscan2
- LRRC4B | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 228/459 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as rs755799431, COSV100975826; called by muse, mutect2, varscan2
- LRRC55 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 299/633 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746237672; called by muse, mutect2, varscan2
- LRRC59 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs1324724093, COSV56815613; called by muse, mutect2, varscan2
- LRRC66 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 256/548 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755573156, COSV58632802; called by muse, mutect2, varscan2
- LRRC8A | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 286/612 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs779436649; called by muse, mutect2, varscan2
- LRRN2 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 265/555 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs1227136855; called by muse, mutect2, varscan2
- LSG1 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 220/647 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539406568, COSV54570804; called by muse, mutect2, varscan2
- LY75 | c.3793C>T p.H1265Y | Missense Mutation (SNP) | VAF 150/309 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55112407; called by muse, mutect2, varscan2
- MAB21L3 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 197/433 reads (45%) | catalogued as rs753934721, COSV101046292; called by muse, varscan2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 234/439 reads (53%) | catalogued as rs775539898; called by mutect2, varscan2
- MAN2A1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 164/370 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as rs775301628, COSV54846985; called by muse, mutect2, varscan2
- MAN2B1 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 232/491 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs138817592, COSV55470021; called by muse, mutect2, varscan2
- MAN2C1 | c.3043C>T p.R1015W | Missense Mutation (SNP) | VAF 166/362 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs139418901; called by muse, varscan2
- MARCHF11 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs185990656, COSV60127129; called by muse, mutect2, varscan2
- MARCHF8 | c.288del p.C97Afs*40 | Frame Shift Del (DEL) | VAF 252/467 reads (54%) | catalogued as COSV100165865; called by mutect2, varscan2
- MATN2 | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 131/474 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754086233, COSV54711976; called by muse, mutect2, varscan2
- MBD6 | c.2080dup p.Q694Pfs*23 | Frame Shift Ins (INS) | VAF 58/154 reads (38%) | catalogued as rs762648935; called by mutect2, varscan2
- MBTPS1 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58572100; called by muse, mutect2, varscan2
- MCC | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 200/465 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1402103100; called by muse, mutect2, varscan2
- MCM7 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 263/493 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); catalogued as rs147404515; called by muse, mutect2, varscan2
- MDGA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 245/504 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1327917945; called by muse, mutect2, varscan2
- MED1 | c.437del p.N146Ifs*24 | Frame Shift Del (DEL) | VAF 132/258 reads (51%) | catalogued as COSV56125174; called by mutect2, varscan2
- MED23 | c.3079G>A p.V1027I | Missense Mutation (SNP) | VAF 202/463 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1167434123, COSV100645389; called by muse, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 250/533 reads (47%) | catalogued as rs745558596; called by mutect2, varscan2
- MEGF6 | c.4528C>T p.R1510W | Missense Mutation (SNP) | VAF 231/492 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs773757401; called by muse, mutect2, varscan2
- MEGF8 | c.4669G>A p.E1557K (on ENST00000251268 / NM_001271938.2; = p.E1490K on NM_001410.3) | Missense Mutation (SNP) | VAF 285/567 reads (50%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.826); catalogued as rs767649270; called by muse, mutect2, varscan2
- MEX3D | c.1726del p.L576Wfs*33 | Frame Shift Del (DEL) | VAF 285/616 reads (46%) | catalogued as rs1487685986; called by mutect2, varscan2
- MIA2 | c.1089dup p.D364Rfs*5 | Frame Shift Ins (INS) | VAF 132/312 reads (42%) | catalogued as rs538500709; called by mutect2, varscan2
- MICU3 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 132/276 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs199831377, COSV58849897; called by muse, mutect2, varscan2
- MOCOS | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 262/503 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs533326490; called by muse, mutect2, varscan2
- MPIG6B | c.320dup p.C108Lfs*72 | Frame Shift Ins (INS) | VAF 324/653 reads (50%) | catalogued as rs1343823890; called by mutect2, varscan2
- MPO | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 210/399 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs765429248, COSV56562794; called by muse, mutect2, varscan2
- MPPED1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 111/549 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769533468, COSV61987318, COSV61988713; called by muse, mutect2, varscan2
- MROH5 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 197/649 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs751096278; called by muse, mutect2, varscan2
- MROH5 | c.92dup p.V32Cfs*70 | Frame Shift Ins (INS) | VAF 80/363 reads (22%) | catalogued as rs748849454; called by mutect2, varscan2
- MRPL2 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 159/308 reads (52%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.77); catalogued as rs758103606; called by muse, mutect2, varscan2
- MSANTD4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 197/431 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs751543630, COSV57285240; called by muse, mutect2, varscan2
- MTHFSD | c.949G>A p.A317T (on ENST00000360900 / NM_001159377.2; = p.A316T on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 310/621 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.061); catalogued as rs765817887; called by muse, mutect2, varscan2
- MTMR6 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 85/190 reads (45%) | catalogued as rs750462481, COSV67808481; called by muse, mutect2, varscan2
- MTMR9 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 118/249 reads (47%) | catalogued as rs1429114187, COSV99644632; called by muse, varscan2
- MUC12 | c.4720G>A p.A1574T (on ENST00000379442; = p.A1431T on NM_001164462.1) | Missense Mutation (SNP) | VAF 10/1733 reads (1%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs201941728; called by muse, mutect2
- MUC4 | c.7319C>T p.S2440L | Missense Mutation (SNP) | VAF 307/980 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs752354404; called by muse, varscan2
- MUC5AC | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 187/449 reads (42%) | SIFT tolerated (0.21); catalogued as rs768950562, COSV62254118; called by muse, mutect2, varscan2
- MVP | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 276/553 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62421423; called by muse, mutect2, varscan2
- MXRA5 | c.6182del p.P2061Rfs*68 | Frame Shift Del (DEL) | VAF 321/326 reads (98%) | catalogued as COSV99475235; called by mutect2, varscan2
- MYH7B | c.3116G>A p.R1039Q | Missense Mutation (SNP) | VAF 231/464 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs778547408; called by muse, varscan2
- MYOD1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 193/402 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs753537132; called by muse, mutect2, varscan2
- NAA25 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 174/336 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs972618736; called by muse, varscan2
- NCKAP1 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62940296; called by muse, mutect2, varscan2
- NDC80 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs116875769; called by muse, mutect2, varscan2
- NEDD4 | c.2375C>T p.T792M (on ENST00000508342 / NM_001284338.1; = p.T373M on NM_006154.4) | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369327462; called by muse, mutect2, varscan2
- NEMP1 | c.824G>A p.R275Q (on ENST00000300128 / NM_001130963.2; = p.R202Q on NM_015257.3) | Missense Mutation (SNP) | VAF 226/456 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs767459890, COSV55662459; called by muse, mutect2, varscan2
- NEUROG3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 258/572 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV54342438; called by muse, mutect2, varscan2
- NFATC1 | c.2091C>T p.N697= | Splice Region (SNP) | VAF 407/416 reads (98%) | catalogued as rs772857723, COSV53707821, COSV99501831; called by muse, mutect2, varscan2
- NFATC2 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs151092809; called by muse, mutect2, varscan2
- NFATC4 | c.74del p.P25Rfs*69 | Frame Shift Del (DEL) | VAF 162/330 reads (49%) | catalogued as rs778613456; called by mutect2, varscan2
- NINL | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 271/592 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1358052026, COSV54005267; called by muse, mutect2, varscan2
- NLGN2 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 240/472 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs749178079, COSV57209699; called by muse, mutect2, varscan2
- NLRP7 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 220/484 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs771017377, COSV60170674; called by muse, varscan2
- NMNAT1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 178/397 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs201994921, CM155281, COSV65882648; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 198/404 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 180/410 reads (44%) | catalogued as rs765756993; called by mutect2, varscan2
- NPR1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs368538785; called by muse, mutect2, varscan2
- NPR2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 191/360 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs1296101280; called by muse, mutect2, varscan2
- NPVF | c.206dup p.N69Kfs*4 | Frame Shift Ins (INS) | VAF 224/449 reads (50%) | catalogued as rs766699446; called by mutect2, varscan2
- NSD3 | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 166/502 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752248481; called by muse, mutect2, varscan2
- NUP155 | c.1424C>A p.P475H (on ENST00000231498 / NM_153485.3; = p.P416H on NM_004298.4) | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99192886; called by muse, mutect2, varscan2
- NUP210 | c.3142G>A p.G1048S | Missense Mutation (SNP) | VAF 206/438 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs541868505, COSV54413869; called by muse, mutect2, varscan2
- NUP210 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 276/550 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777253409; called by muse, varscan2
- NVL | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs896029248; called by muse, mutect2, varscan2
- NWD1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 328/627 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as rs560096144; called by muse, mutect2, varscan2
- NXF1 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 215/446 reads (48%) | catalogued as COSV53674975; called by muse, mutect2, varscan2
- NYAP1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 361/762 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.275); catalogued as rs1291253460, COSV55721719; called by muse, mutect2, varscan2
- NYAP2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 227/471 reads (48%) | catalogued as COSV56013284, COSV56015077; called by muse, mutect2, varscan2
- OBP2A | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 217/439 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs780131888; called by muse, mutect2, varscan2
- OBSCN | c.15643C>T p.R5215C | Missense Mutation (SNP) | VAF 189/356 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747153742, COSV52826017, COSV99475007; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 172/320 reads (54%) | catalogued as CD000269; called by mutect2, varscan2
- ODC1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 206/424 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV104374922; called by muse, mutect2, varscan2
- OR2M3 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 191/513 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776150417, COSV101513532, COSV71758983; called by muse, varscan2
- OR2W1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 182/358 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs896592244, COSV65851468; called by muse, varscan2
- OR52A5 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 24/524 reads (5%) | catalogued as rs1406984688, COSV100263474, COSV56614769, COSV56617124; called by muse, mutect2
- OSBPL7 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 199/398 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs746315657, COSV50108164; called by muse, mutect2, varscan2
- OSR2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 296/950 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52558102; called by muse, mutect2, varscan2
- OTOGL | c.5015G>A p.R1672Q (on ENST00000547103; = p.R1663Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/262 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs765255520, COSV100086838, COSV100087488; called by muse, mutect2, varscan2
- OTP | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 306/680 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as rs1233125354; called by muse, mutect2, varscan2
- OXR1 | c.1046G>A p.R349Q (on ENST00000442977 / NM_001198532.1; = p.R348Q on NM_018002.3) | Missense Mutation (SNP) | VAF 183/634 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs776241368, COSV56336553; called by muse, varscan2
- P4HA2 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 168/376 reads (45%) | catalogued as rs200583507; called by muse, mutect2, varscan2
- PACSIN1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 223/429 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99763354; called by muse, mutect2, varscan2
- PACSIN3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 228/462 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs772870340, COSV100096056; called by muse, mutect2, varscan2
- PARP1 | c.1251del p.K418Sfs*2 | Frame Shift Del (DEL) | VAF 260/502 reads (52%) | catalogued as rs779960019; called by mutect2, varscan2
- PC | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 207/425 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs1331922118; called by muse, mutect2, varscan2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2, varscan2
- PCDH1 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 266/568 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs143703336; called by muse, mutect2, varscan2
- PCDHA10 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 340/709 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.477); catalogued as rs782751627, COSV100251009; called by muse, mutect2, varscan2
- PCDHA13 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 242/522 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs371124724; called by muse, varscan2
- PCDHA6 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 158/274 reads (58%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1554131020, COSV65348941, COSV65351681; called by muse, mutect2, varscan2
- PCDHB13 | c.918del p.K306Nfs*30 | Frame Shift Del (DEL) | VAF 126/264 reads (48%) | catalogued as rs782213177; called by mutect2, varscan2
- PCDHB4 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 360/796 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV52023102; called by muse, varscan2
- PCDHB4 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 244/494 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99522043; called by muse, varscan2
- PCDHGA9 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 147/301 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs199556803, COSV53916555; called by muse, mutect2, varscan2
- PCDHGB3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 261/549 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.354); catalogued as rs771102617, COSV54016059; called by muse, mutect2, varscan2
- PCDHGC3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 264/518 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs199871912; called by muse, mutect2, varscan2
- PCK1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100100354, COSV60128154; called by muse, mutect2, varscan2
- PCK1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 203/475 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753855895; called by muse, mutect2, varscan2
- PDE1B | c.1565dup p.S523Ifs*6 | Frame Shift Ins (INS) | VAF 182/418 reads (44%) | catalogued as rs780236743; called by mutect2, varscan2
- PDE3A | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 270/580 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1259801479; called by muse, mutect2, varscan2
- PDE4D | c.241dup p.L81Pfs*74 | Frame Shift Ins (INS) | VAF 64/162 reads (40%) | catalogued as rs1184611767; ClinVar: uncertain significance; called by mutect2, varscan2
- PDLIM2 | c.208C>T p.R70C (on ENST00000397760; = p.R320C on NM_021630.6) | Missense Mutation (SNP) | VAF 274/912 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1166754916, COSV56133603; called by muse, mutect2, varscan2
- PDZD2 | c.4426C>T p.P1476S | Missense Mutation (SNP) | VAF 266/610 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56865174; called by muse, varscan2
- PFKL | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 246/516 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs771637190; called by muse, mutect2, varscan2
- PHACTR1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 169/362 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs377313232; called by muse, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 152/368 reads (41%) | catalogued as rs769717544; called by mutect2, varscan2
- PHRF1 | c.3052C>T p.R1018C (on ENST00000264555 / NM_001286581.2; = p.R1017C on NM_020901.4) | Missense Mutation (SNP) | VAF 384/811 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs755509223; called by muse, mutect2, varscan2
- PIDD1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 305/674 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs779465093, COSV61705492, COSV61706380; called by muse, mutect2, varscan2
- PIEZO1 | c.3514G>C p.V1172L | Missense Mutation (SNP) | VAF 256/510 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as rs1409761888; called by muse, mutect2, varscan2
- PIP5KL1 | c.638G>A p.R213H (on ENST00000388747 / NM_001135219.2; = p.R10H on NM_173492.1) | Missense Mutation (SNP) | VAF 252/573 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55945400; called by muse, mutect2, varscan2
- PITRM1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 201/416 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs760564399; called by muse, mutect2
- PKD2 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 231/482 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs377398357, COSV52938858; called by muse, mutect2, varscan2
- PKHD1L1 | c.6850C>T p.R2284W | Missense Mutation (SNP) | VAF 150/525 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201214727; called by muse, varscan2
- PKHD1L1 | c.8303G>A p.G2768E | Missense Mutation (SNP) | VAF 239/718 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65746830; called by muse, mutect2, varscan2
- PLCD1 | c.1804G>A p.V602M | Missense Mutation (SNP) | VAF 286/591 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376384426; called by muse, mutect2, varscan2
- PLEKHA7 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100850333; called by muse, mutect2, varscan2
- PLPP4 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 182/400 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774344764; called by muse, mutect2, varscan2
- PLXNA3 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs145388937, COSV63755529; called by muse, mutect2, varscan2
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 166/178 reads (93%) | catalogued as rs781891121, COSV61745231; called by mutect2, varscan2
- POLE | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 182/382 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57681803; called by muse, varscan2
- POLR3E | c.1782dup p.G595Rfs*39 | Frame Shift Ins (INS) | VAF 182/427 reads (43%) | catalogued as rs777556882; called by mutect2, varscan2
- POLRMT | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 276/536 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs780855603; called by muse, mutect2, varscan2
- POTEJ | c.2126del p.G709Afs*20 | Frame Shift Del (DEL) | VAF 285/614 reads (46%) | catalogued as rs1275085181; called by mutect2, varscan2
- POTEM | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 234/650 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs773421412, COSV69152945; called by muse, varscan2
- POU3F2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 304/611 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1274589449, COSV100098907; called by muse, varscan2
- PPP1R9A | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1195259609; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 48/94 reads (51%) | catalogued as rs758484975; called by mutect2, varscan2
- PRC1 | c.1542del p.V515Cfs*42 | Frame Shift Del (DEL) | VAF 192/354 reads (54%) | catalogued as COSV62694905; called by mutect2, varscan2
- PRKAA2 | c.1295T>C p.V432A | Missense Mutation (SNP) | VAF 124/235 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.407); catalogued as rs752943476; called by muse, mutect2, varscan2
- PRKCD | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs782458851, COSV100388191; called by muse, varscan2
- PROSER2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 344/690 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs763957726; called by muse, mutect2, varscan2
- PRRT4 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 326/624 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1461305349; called by muse, mutect2, varscan2
- PSMD12 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370653363; called by muse, mutect2, varscan2
- PTCH1 | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 245/507 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766037357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH1R | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 234/479 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.115); catalogued as rs779982498, COSV57317842; called by muse, mutect2, varscan2
- PTPMT1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779209792, COSV100442819; called by muse, mutect2, varscan2
- PTPN14 | c.3307A>G p.T1103A | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV65283806; called by muse, mutect2, varscan2
- PTPN9 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 210/432 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs367823360; called by muse, varscan2
- PTPRG | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 188/426 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs751360182; called by muse, mutect2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 124/240 reads (52%) | catalogued as rs1179811215; called by mutect2, varscan2
- PUS1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 277/591 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs770654583, COSV59034709, COSV59035414; called by muse, mutect2, varscan2
- PUS7 | c.1933del p.M645Wfs*11 | Frame Shift Del (DEL) | VAF 192/360 reads (53%) | catalogued as rs1243111253; called by mutect2, varscan2
- PXDNL | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 239/814 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759582960, COSV99080550; called by muse, mutect2, varscan2
- RAB6C | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 174/532 reads (33%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs747296971, COSV69339855; called by muse, mutect2
- RAC2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 182/400 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV50774054; called by muse, mutect2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 324/596 reads (54%) | catalogued as rs767679528; called by mutect2, varscan2
- RANBP2 | c.6944del p.P2315Lfs*5 | Frame Shift Del (DEL) | VAF 189/409 reads (46%) | catalogued as COSV99311854; called by mutect2, varscan2
- RASA3 | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV61866093; called by muse, mutect2, varscan2
- RBM15B | c.2529dup p.S844Vfs*121 | Frame Shift Ins (INS) | VAF 238/502 reads (47%) | catalogued as rs781825075; called by mutect2, varscan2
- REG1B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 174/352 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs749277780, COSV59307427; called by muse, varscan2
- RHBDF2 | c.932dup p.L312Tfs*52 | Frame Shift Ins (INS) | VAF 166/414 reads (40%) | catalogued as rs756639910; called by mutect2, varscan2
- RHBDF2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 141/242 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs759211203, COSV57421544; called by muse, mutect2, varscan2
- RIC8A | c.1276A>G p.M426V (on ENST00000526104 / NM_001286134.1; = p.M432V on NM_021932.5) | Missense Mutation (SNP) | VAF 235/516 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs1308237937; called by muse, mutect2, varscan2
- RIMBP2 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 250/565 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200419075, COSV55470298; called by muse, mutect2, varscan2
- RIPK4 | c.1805G>A p.R602H (on ENST00000352483; = p.R554H on NM_020639.3) | Missense Mutation (SNP) | VAF 296/576 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs764286644, COSV60185599; called by muse, mutect2, varscan2
- RNF207 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 315/645 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as rs567614508; called by muse, mutect2, varscan2
- RNF213 | c.3178G>A p.V1060I | Missense Mutation (SNP) | VAF 133/289 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs537205707; called by muse, mutect2, varscan2
- RNF26 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 246/518 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs779237173, COSV60990878; called by muse, varscan2
- ROBO3 | c.4076G>A p.R1359Q | Missense Mutation (SNP) | VAF 295/624 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.096); catalogued as rs767737763, COSV60625785; called by muse, mutect2, varscan2
- ROGDI | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 272/554 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as rs756917973; called by muse, mutect2, varscan2
- RPRD2 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 89/497 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1406382824; called by muse, mutect2, varscan2
- RPS5 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 247/559 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV99545173; called by muse, mutect2, varscan2
- RRAD | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 267/575 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1420095574, COSV55336293; called by muse, mutect2, varscan2
- RRBP1 | c.3182C>T p.A1061V (on ENST00000377813 / NM_001365613.2; = p.A628V on NM_004587.3) | Missense Mutation (SNP) | VAF 190/419 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs371943538; called by muse, mutect2, varscan2
- RTTN | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 292/296 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs377209454; called by muse, mutect2, varscan2
- RYR1 | c.14716G>A p.A4906T | Missense Mutation (SNP) | VAF 219/465 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1467742744, COSV100617115; called by muse, mutect2, varscan2
- SALL1 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 226/463 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV51762152; called by muse, mutect2, varscan2
- SALL1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 263/492 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV51752910, COSV51760752; called by muse, mutect2, varscan2
- SALL4 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 228/465 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751089738, COSV53854036; called by muse, mutect2, varscan2
- SBNO2 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 222/498 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766814893, COSV62318660; called by muse, mutect2
- SCAP | c.862del p.V289* | Frame Shift Del (DEL) | VAF 190/457 reads (42%) | catalogued as COSV99652441; called by mutect2, varscan2
- SCML4 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 167/376 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as rs1462271155; called by muse, mutect2, varscan2
- SCN2A | c.4990G>A p.G1664S | Missense Mutation (SNP) | VAF 330/624 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99332149; called by muse, mutect2, varscan2
- SCN8A | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 146/297 reads (49%) | catalogued as rs1555225521, CM1513581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.3806G>A p.R1269H | Missense Mutation (SNP) | VAF 263/873 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139752599; called by muse, varscan2
- SCRIB | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 400/1163 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs760633347, COSV100254332; called by muse, mutect2, varscan2
- SDK1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1411123903; called by muse, mutect2, varscan2
- SEC14L2 | c.785del p.G262Vfs*13 | Frame Shift Del (DEL) | VAF 157/326 reads (48%) | catalogued as COSV57240319; called by mutect2, varscan2
- SEC23A | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs1010225972, COSV56979022; called by muse, mutect2, varscan2
- SEMA3F | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 171/375 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1038030098, COSV50029848; called by muse, mutect2, varscan2
- SETBP1 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 240/480 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767260608, COSV56341427; ClinVar: uncertain significance; called by muse, varscan2
- SEZ6L2 | c.1691G>A p.R564H (on ENST00000308713 / NM_001114099.3; = p.R494H on NM_012410.4) | Missense Mutation (SNP) | VAF 213/422 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1311011521, COSV58096855; called by muse, mutect2, varscan2
- SH2B3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 308/635 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV57985201, COSV57988042; called by muse, mutect2, varscan2
- SH2D4B | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 173/373 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs978934366; called by muse, mutect2, varscan2
- SHARPIN | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 152/512 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1402361068; called by muse, mutect2, varscan2
- SHMT1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 154/291 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208262475, COSV57399421; called by muse, mutect2, varscan2
- SIL1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 146/370 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781449770, COSV54530317; called by muse, mutect2, varscan2
- SIPA1L3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 412/808 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377070862; called by muse, mutect2, varscan2
- SIRT2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 160/343 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430999088, COSV99979177; called by muse, mutect2, varscan2
- SKIDA1 | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1452899543; called by muse, mutect2, varscan2
- SLAIN2 | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 257/455 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs760951825; called by muse, mutect2, varscan2
- SLC12A3 | c.2908G>A p.A970T (on ENST00000563236 / NM_001126108.2; = p.A979T on NM_000339.3) | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs534138382; called by muse, mutect2, varscan2
- SLC12A5 | c.2408G>A p.R803H (on ENST00000454036 / NM_001134771.2; = p.R780H on NM_020708.5) | Missense Mutation (SNP) | VAF 241/478 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs779096129, COSV54793253; called by muse, mutect2, varscan2
- SLC25A30 | c.777del p.F259Lfs*12 | Frame Shift Del (DEL) | VAF 144/310 reads (46%) | catalogued as rs754868559; called by mutect2, varscan2
- SLC26A8 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs754358341, COSV100839487; called by muse, mutect2, varscan2
- SLC2A14 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 256/567 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148820254, COSV100533569; called by muse, mutect2, varscan2
- SLC2A4RG | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99829187; called by muse, mutect2
- SLC30A9 | c.631del p.I211Yfs*2 | Frame Shift Del (DEL) | VAF 41/125 reads (33%) | catalogued as COSV100048624; called by mutect2, varscan2
- SLC39A4 | c.1174G>A p.E392K (on ENST00000301305 / NM_001374839.1; = p.E367K on NM_017767.3) | Missense Mutation (SNP) | VAF 230/787 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.103); catalogued as rs367660059; called by muse, mutect2, varscan2
- SLC6A9 | c.965T>C p.F322S (on ENST00000360584 / NM_201649.4; = p.F268S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 215/416 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs1418177620; called by muse, mutect2, varscan2
- SLC9C1 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.172); catalogued as COSV99997424; called by muse, mutect2, varscan2
- SLX4 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 224/473 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs377135500; called by muse, mutect2, varscan2
- SMARCA4 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 246/560 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1568416700, COSV60794306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG5 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 193/366 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV52744654; called by muse, mutect2, varscan2
- SMTN | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 276/491 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs757916551; called by muse, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 148/299 reads (49%) | catalogued as rs768873484; called by mutect2, varscan2
- SOCS6 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 479/488 reads (98%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756162788, COSV67547000; called by muse, mutect2, varscan2
- SORBS1 | c.3650C>T p.A1217V (on ENST00000361941 / NM_001034954.2; = p.A609V on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/370 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.993); catalogued as COSV53359864; called by muse, mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 52/326 reads (16%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SP8 | c.238G>A p.A80T (on ENST00000361443 / NM_198956.4; = p.A98T on NM_182700.6) | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1366866360; called by muse, varscan2
- SPAG7 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 201/435 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1330551441; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 146/316 reads (46%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPSB1 | c.370del p.L124Cfs*56 | Frame Shift Del (DEL) | VAF 296/575 reads (51%) | catalogued as COSV60165026; called by mutect2, varscan2
- SPTBN5 | c.5792G>A p.R1931H | Missense Mutation (SNP) | VAF 306/623 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as rs757182673, COSV58023484; called by muse, mutect2, varscan2
- SREK1IP1 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 165/342 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs762213734, COSV72486304; called by muse, varscan2
- SRRM2 | c.6047G>A p.R2016H | Missense Mutation (SNP) | VAF 274/553 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as rs760153809, COSV51940638; called by muse, mutect2, varscan2
- SRXN1 | c.52del p.A18Rfs*29 | Frame Shift Del (DEL) | VAF 212/448 reads (47%) | catalogued as rs1266455729; called by mutect2, varscan2
- ST6GALNAC5 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 266/570 reads (47%) | PolyPhen probably damaging (0.993); catalogued as rs755409104, COSV59570371; called by muse, varscan2
- ST6GALNAC6 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 255/496 reads (51%) | PolyPhen benign (0.047); catalogued as rs112251327, COSV99398473; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 128/272 reads (47%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAG2 | c.3613C>T p.R1205* | Nonsense Mutation (SNP) | VAF 195/195 reads (100%) | catalogued as rs867285087, COSV54355049; called by muse, mutect2, varscan2
- STK11IP | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 320/672 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs750923053; called by muse, mutect2
- STK32B | c.30dup p.V11Rfs*3 | Frame Shift Ins (INS) | VAF 68/460 reads (15%) | catalogued as rs780983138; called by mutect2, varscan2
- STON1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 231/444 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147440328, COSV100562377; called by muse, mutect2, varscan2
- STXBP5L | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 202/431 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs573081224; called by muse, mutect2, varscan2
- SYCP1 | c.1884del p.G629Vfs*8 | Frame Shift Del (DEL) | VAF 72/154 reads (47%) | catalogued as rs762984894, COSV65697419; called by mutect2, varscan2
- SYMPK | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV55610302, COSV55612995; called by muse, mutect2, varscan2
- SYNE1 | c.18157C>T p.R6053* (on ENST00000367255 / NM_182961.4; = p.R5982* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 179/395 reads (45%) | catalogued as rs1562775040, COSV54919479; called by muse, mutect2, varscan2
- SYT17 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 222/479 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs766798976; called by muse, mutect2, varscan2
- SYT3 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 325/646 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs548116502, COSV58895512, COSV58898622; called by muse, mutect2, varscan2
- TACC2 | c.6047C>T p.P2016L (on ENST00000334433; = p.P94L on NM_006997.4) | Missense Mutation (SNP) | VAF 207/423 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs564717762; called by muse, mutect2, varscan2
- TAF11L13 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV72825568; called by muse, mutect2, varscan2
- TAF1C | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 211/412 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1390845067, COSV58987575; called by muse, mutect2, varscan2
- TBC1D9B | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 306/585 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756019909, COSV62281366; called by muse, mutect2, varscan2
- TCF20 | c.4118C>T p.A1373V | Missense Mutation (SNP) | VAF 338/719 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.384); catalogued as rs148859074; called by muse, mutect2, varscan2
- TCF3 | c.1573del p.R525Gfs*76 | Frame Shift Del (DEL) | VAF 252/528 reads (48%) | catalogued as COSV53646783, COSV53650404; called by mutect2, varscan2
- TCHH | c.4210C>T p.R1404C | Missense Mutation (SNP) | VAF 272/491 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs367869823; called by muse, mutect2, varscan2
- TEKT3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 221/456 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777321677; called by muse, mutect2, varscan2
- TENM4 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 366/727 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.994); catalogued as rs775103927; called by muse, mutect2, varscan2
- TENT4A | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 178/401 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766747987, COSV50098074; called by muse, mutect2, varscan2
- TESC | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 229/428 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs147019006; called by muse, mutect2, varscan2
- TESK2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1044894727, COSV59151548; called by muse, mutect2, varscan2
- TET2 | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373336171, COSV99481829; called by muse, mutect2, varscan2
- TFPT | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 401/780 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1467307059; called by muse, mutect2, varscan2
- TFR2 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 134/299 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373037160; called by muse, mutect2, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 212/462 reads (46%) | catalogued as rs771515402; called by mutect2, varscan2
- TGFBR1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 220/448 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs757374917, CM112279, COSV66624788; called by muse, mutect2, varscan2
- TGM2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 186/410 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs967969723; called by muse, mutect2, varscan2
- THOC1 | c.1107dup p.D370Rfs*16 | Frame Shift Ins (INS) | VAF 125/277 reads (45%) | catalogued as rs778021280; called by mutect2, varscan2
- THPO | c.1283T>C p.L428P (on ENST00000649095 / NM_001290003.1; = p.L288P on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 209/700 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.99); catalogued as rs779419597; called by muse, mutect2, varscan2
- THRAP3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 253/488 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV63567920; called by muse, mutect2, varscan2
- THSD7A | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 134/286 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768811769, COSV70259831, COSV70264422; called by muse, mutect2, varscan2
- TICRR | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779488758, COSV51538035; called by muse, mutect2, varscan2
- TINCR | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 218/488 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1375291968; called by muse, varscan2
- TJP3 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 322/672 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs904636776; called by muse, mutect2, varscan2
- TKFC | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 173/359 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1446648523; called by muse, varscan2
- TMC5 | c.1703T>C p.L568P (on ENST00000396229 / NM_001105248.1; = p.L322P on NM_024780.5) | Missense Mutation (SNP) | VAF 221/445 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54901513; called by muse, mutect2, varscan2
- TMEM150B | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 296/627 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773129407; called by muse, mutect2, varscan2
- TMEM204 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 217/423 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.797); catalogued as rs780085186; called by muse, mutect2, varscan2
- TMEM245 | c.2344T>C p.F782L | Missense Mutation (SNP) | VAF 95/425 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs1205217408; called by muse, mutect2, varscan2
- TMEM44 | c.803C>T p.S268L (on ENST00000392432 / NM_001166305.2; = p.S221L on NM_138399.5) | Missense Mutation (SNP) | VAF 227/676 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs140177882; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 142/160 reads (89%) | catalogued as rs781830688; called by mutect2, varscan2
- TNNI2 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 257/530 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780745718, COSV99425576; called by muse, mutect2, varscan2
- TNXB | c.11437G>A p.D3813N (on ENST00000647633; = p.D3566N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 221/927 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.652); catalogued as rs746909022; called by muse, mutect2, varscan2
- TOM1 | c.1168del p.Q390Kfs*163 | Frame Shift Del (DEL) | VAF 176/350 reads (50%) | catalogued as rs1458068443, COSV65898445; called by mutect2, varscan2
- TOX2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs550731186; called by muse, mutect2, varscan2
- TPP2 | c.3427G>A p.G1143R | Missense Mutation (SNP) | VAF 223/458 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs756043080, COSV101060356, COSV65752570; called by muse, mutect2, varscan2
- TPST2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 240/492 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs770123108; called by muse, varscan2
- TPST2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 206/443 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as rs745848347; called by muse, mutect2, varscan2
- TRAC | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 177/388 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746704084; called by muse, mutect2, varscan2
- TRAF2 | c.26del p.P9Lfs*77 | Frame Shift Del (DEL) | VAF 165/328 reads (50%) | catalogued as rs748531430; called by mutect2, varscan2
- TRIM23 | c.1157G>A p.S386N | Missense Mutation (SNP) | VAF 212/426 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV51552261; called by muse, mutect2, varscan2
- TRIOBP | c.5873G>A p.R1958Q (on ENST00000644935 / NM_001039141.3; = p.R245Q on NM_007032.5) | Missense Mutation (SNP) | VAF 343/693 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1269802321, COSV58525862; called by muse, mutect2, varscan2
- TSC2 | c.3100G>A p.V1034I | Missense Mutation (SNP) | VAF 208/386 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs146745242; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TST | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 166/364 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs138956044; called by muse, mutect2, varscan2
- TTC14 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 184/594 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56012972; called by muse, mutect2, varscan2
- TTC34 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 138/613 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs1034477692; called by muse, mutect2, varscan2
- TTC6 | c.2997del p.D1000Tfs*2 | Frame Shift Del (DEL) | VAF 122/296 reads (41%) | catalogued as rs767436917; called by mutect2, varscan2
- TTLL11 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 274/582 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as rs571306604, COSV100388822; called by muse, mutect2, varscan2
- TTLL13P | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 136/310 reads (44%) | catalogued as rs776615886; called by muse, mutect2
- TTN | c.41680C>T p.R13894* (on ENST00000591111; = p.R6470* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 238/462 reads (52%) | catalogued as rs764654357, COSV60160194; called by muse, varscan2
- UBE4A | c.2356C>T p.R786C (on ENST00000252108 / NM_001204077.2; = p.R793C on NM_004788.4) | Missense Mutation (SNP) | VAF 188/428 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs782602634; called by muse, varscan2
- UBR4 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 145/289 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200068490; called by muse, mutect2, varscan2
- UGDH | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 147/336 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs148161041; called by muse, mutect2, varscan2
- UGT2B7 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 223/494 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1000966644, COSV59442326; called by muse, varscan2
- UNC13D | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 334/679 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.689); catalogued as rs778432670; called by muse, mutect2, varscan2
- UNC5CL | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 203/405 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139674158; called by muse, mutect2, varscan2
- UNCX | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1309462785; called by muse, mutect2, varscan2
- UNK | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 209/442 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs566260739; called by muse, mutect2, varscan2
- USH2A | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 252/546 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs760741238, COSV100238840; ClinVar: uncertain significance; called by muse, mutect2
- USP32 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); catalogued as COSV99039718; called by muse, mutect2, varscan2
- VARS1 | c.3262G>A p.V1088I | Missense Mutation (SNP) | VAF 50/816 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.9); catalogued as rs745322193; called by muse, mutect2
- VPS13C | c.6767C>T p.T2256M (on ENST00000644861 / NM_020821.3; = p.T2213M on NM_017684.5) | Missense Mutation (SNP) | VAF 200/453 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs200174382, COSV51428973; called by muse, mutect2, varscan2
- VPS13C | c.3313G>A p.A1105T (on ENST00000644861 / NM_020821.3; = p.A1062T on NM_017684.5) | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs747305996; called by muse, mutect2, varscan2
- VPS13C | c.2296A>G p.T766A (on ENST00000644861 / NM_020821.3; = p.T723A on NM_017684.5) | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1452940442; called by muse, mutect2, varscan2
- VWA3A | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769351508; called by muse, mutect2, varscan2
- VWF | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 131/318 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs867631561; called by muse, mutect2, varscan2
- WDPCP | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 168/337 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs149347732, COSV55423948; called by muse, mutect2, varscan2
- WDR5 | c.648dup p.V217Rfs*42 | Frame Shift Ins (INS) | VAF 82/264 reads (31%) | catalogued as rs780890680; called by mutect2, varscan2
- WDR90 | c.1545del p.F515Lfs*31 | Frame Shift Del (DEL) | VAF 166/370 reads (45%) | catalogued as rs1567216009; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 146/284 reads (51%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK2 | c.3077G>A p.G1026D | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1162832013, COSV52948756; called by muse, mutect2, varscan2
- WNK2 | c.6716C>T p.P2239L (on ENST00000297954 / NM_001282394.1; = p.P2202L on NM_006648.3) | Missense Mutation (SNP) | VAF 248/505 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.024); catalogued as rs377748076, COSV99943771; called by muse, mutect2, varscan2
- WNK4 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 224/433 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53820459; called by muse, varscan2
- WNT5B | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 275/553 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs780859010; called by muse, mutect2, varscan2
- WSCD2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 161/317 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565967983, COSV54587083, COSV54587557; called by muse, varscan2
- XKR4 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 267/732 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1168655457; called by muse, mutect2, varscan2
- XPO5 | c.1529del p.L510Wfs*12 | Frame Shift Del (DEL) | VAF 127/265 reads (48%) | catalogued as rs756386937; called by mutect2, varscan2
- YLPM1 | c.4993C>T p.R1665C | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs762333936, COSV53118872; called by muse, mutect2, varscan2
- ZBTB1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 229/472 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62438483; called by muse, varscan2
- ZBTB18 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 264/549 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1423296558, COSV62396368; called by muse, mutect2, varscan2
- ZC3H13 | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 210/429 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV99667716; called by muse, mutect2, varscan2
- ZC3H14 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 156/305 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs772979062, COSV51768548; called by muse, mutect2, varscan2
- ZC3H7B | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 217/500 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60960824; called by muse, mutect2, varscan2
- ZDBF2 | c.2998del p.T1000Qfs*3 | Frame Shift Del (DEL) | VAF 186/358 reads (52%) | catalogued as rs1559154594; called by mutect2, varscan2
- ZDHHC8 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 171/321 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777641343, COSV57713103; called by muse, mutect2, varscan2
- ZFAT | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 244/775 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs374100557; called by muse, mutect2, varscan2
- ZFHX4 | c.8740G>A p.G2914R | Missense Mutation (SNP) | VAF 200/618 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50692431; called by muse, mutect2, varscan2
- ZMIZ2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 226/472 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1424925109; called by muse, mutect2, varscan2
- ZMYND10 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.586); catalogued as COSV99027833; called by muse, mutect2, varscan2
- ZNF330 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV53707437; called by muse, mutect2, varscan2
- ZNF449 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 279/279 reads (100%) | catalogued as COSV100202996; called by muse, mutect2, varscan2
- ZNF497 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 231/515 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54049567; called by muse, mutect2, varscan2
- ZNF516 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 452/461 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374836539; called by muse, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 106/225 reads (47%) | catalogued as rs782441698; called by mutect2, varscan2
- ZNF654 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 175/379 reads (46%) | catalogued as COSV71897499; called by muse, mutect2, varscan2
- ZNF687 | c.3236G>A p.R1079H | Missense Mutation (SNP) | VAF 212/416 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs776454096; called by muse, mutect2, varscan2
- ZNF696 | c.189del p.P64Lfs*297 | Frame Shift Del (DEL) | VAF 262/808 reads (32%) | catalogued as rs752583377, COSV57525921; called by mutect2, varscan2
- ZNF697 | c.1547C>T p.T516M | Missense Mutation (SNP) | VAF 308/642 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268649653, COSV70284359; called by muse, mutect2, varscan2
- ZNF707 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 364/1123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781806274; called by muse, mutect2, varscan2
- ZNF750 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 170/364 reads (47%) | catalogued as COSV99489810; called by muse, mutect2, varscan2
- ZNF784 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 307/683 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs776234782; called by muse, mutect2, varscan2
- ZNF83 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 304/648 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56529226; called by muse, varscan2
- ZSCAN32 | c.131A>G p.Y44C (on ENST00000396846; = p.Y45C on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/365 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1256086157; called by muse, mutect2, varscan2
- ZSWIM1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 294/594 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs752626211, COSV99666507; called by muse, mutect2, varscan2
- AAGAB | c.698A>C p.Q233P | Missense Mutation (SNP) | VAF 167/348 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ABAT | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 169/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA6 | c.1095del p.F365Lfs*7 | Frame Shift Del (DEL) | VAF 132/252 reads (52%) | called by mutect2, varscan2
- ABCC5 | c.433A>C p.N145H | Missense Mutation (SNP) | VAF 148/474 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ABCE1 | c.1639A>G p.S547G | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACER2 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 215/427 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTL7B | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 238/453 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ACYP2 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 189/416 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 314/671 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 229/509 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRA2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 247/687 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ADRA2A | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 248/471 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRB3 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 263/884 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- AGBL1 | c.2083T>C p.Y695H | Missense Mutation (SNP) | VAF 125/257 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AHR | c.1736A>C p.D579A | Missense Mutation (SNP) | VAF 180/354 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKAL2 | c.53C>G p.A18G | Missense Mutation (SNP) | VAF 251/469 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.343); called by mutect2, varscan2
- ALYREF | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AMER3 | c.1054del p.L352Sfs*144 | Frame Shift Del (DEL) | VAF 222/523 reads (42%) | called by mutect2, varscan2
- ANKFN1 | c.3572C>T p.A1191V (on ENST00000653862; = p.A1044V on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/377 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ANKRD36C | c.2630del p.K877Rfs*17 | Frame Shift Del (DEL) | VAF 130/254 reads (51%) | called by mutect2, varscan2
- ANO6 | c.1123A>G p.S375G | Missense Mutation (SNP) | VAF 163/326 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, varscan2
- AP3B2 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 122/289 reads (42%) | called by muse, mutect2, varscan2
- APC2 | c.5530C>T p.H1844Y | Missense Mutation (SNP) | VAF 349/675 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ARHGAP17 | c.320_321del p.E107Afs*9 | Frame Shift Del (DEL) | VAF 166/370 reads (45%) | called by mutect2, varscan2
- ARHGAP39 | c.1721G>A p.S574N | Missense Mutation (SNP) | VAF 361/1076 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ARHGEF15 | c.1822A>T p.T608S | Missense Mutation (SNP) | VAF 212/411 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ARHGEF17 | c.5869dup p.R1957Pfs*67 | Frame Shift Ins (INS) | VAF 267/569 reads (47%) | called by mutect2, varscan2
- ARID1A | c.3302_3303del p.Y1101Cfs*3 | Frame Shift Del (DEL) | VAF 188/456 reads (41%) | called by mutect2, varscan2
- ARID2 | c.1130T>A p.I377N | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARSJ | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD5 | c.812T>A p.L271* | Nonsense Mutation (SNP) | VAF 176/358 reads (49%) | called by muse, mutect2, varscan2
- ATE1 | c.1513del p.V505Wfs*42 | Frame Shift Del (DEL) | VAF 182/388 reads (47%) | called by mutect2, varscan2
- ATP2A2 | c.1308del p.V437Lfs*12 | Frame Shift Del (DEL) | VAF 130/274 reads (47%) | called by mutect2, varscan2
- ATRN | c.693del p.F231Lfs*8 | Frame Shift Del (DEL) | VAF 134/260 reads (52%) | called by mutect2, varscan2
- BCHE | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 343/537 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCKDK | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 159/335 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- BMT2 | c.973del p.T325Pfs*23 | Frame Shift Del (DEL) | VAF 168/380 reads (44%) | called by mutect2, varscan2
- BRF1 | c.876del p.S293Rfs*11 | Frame Shift Del (DEL) | VAF 164/335 reads (49%) | called by mutect2, varscan2
- BTN2A2 | c.881del p.K294Rfs*56 | Frame Shift Del (DEL) | VAF 193/383 reads (50%) | called by mutect2, varscan2
- C12orf54 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 161/343 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C4A | c.2563C>T p.L855F | Missense Mutation (SNP) | VAF 176/450 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C8A | c.1341del p.R448Gfs*3 | Frame Shift Del (DEL) | VAF 180/386 reads (47%) | called by mutect2, varscan2
- C9orf131 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 262/542 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CACNA1E | c.6505del p.L2169Sfs*7 (on ENST00000367573 / NM_001205293.3; = p.L2126Sfs*7 on NM_000721.4) | Frame Shift Del (DEL) | VAF 240/504 reads (48%) | called by mutect2, varscan2
- CACNA1I | c.6567del p.G2190Afs*82 | Frame Shift Del (DEL) | VAF 251/546 reads (46%) | called by mutect2, varscan2
- CACNG8 | c.55del p.V19Cfs*5 | Frame Shift Del (DEL) | VAF 275/556 reads (49%) | called by mutect2, varscan2
- CACUL1 | c.321dup p.T108Hfs*23 | Frame Shift Ins (INS) | VAF 140/324 reads (43%) | called by mutect2, varscan2
- CALHM5 | c.738del p.F246Lfs*75 | Frame Shift Del (DEL) | VAF 204/419 reads (49%) | called by mutect2, varscan2
- CAMP | c.211G>A p.D71N (on ENST00000296435; = p.D68N on NM_004345.5) | Missense Mutation (SNP) | VAF 156/302 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAMSAP1 | c.1772del p.F591Sfs*5 | Frame Shift Del (DEL) | VAF 236/500 reads (47%) | called by mutect2, varscan2
- CARS2 | c.1091A>G p.Q364R | Missense Mutation (SNP) | VAF 289/548 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAV2 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC102B | c.1193dup p.N398Kfs*2 | Frame Shift Ins (INS) | VAF 261/274 reads (95%) | called by mutect2, varscan2
- CCDC15 | c.228dup p.Q77Tfs*12 | Frame Shift Ins (INS) | VAF 86/194 reads (44%) | called by mutect2, varscan2
- CCDC170 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 270/493 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
904 further variants in this file (413 protein-altering or splice-affecting, 435 silent, 56 other) are not listed here.
